Somatic mutation profile of tumor specimen MMRF_1454_1_BM_CD138pos (aliquot MMRF_1454_1_BM_CD138pos_T1_KAS5U_L01602) from MMRF case MMRF_1454, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.7 years (19,632 days).
Specimen MMRF_1454_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c793461-4b95-4587-8ea0-d19b053ea182.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1454_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1454_1_PB_Whole_C2_KAS5U_L01611; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9ffe955-485e-4709-9dd3-e6a7e0cc00d3

The open-access MAF lists 161 somatic variants for this specimen: 58 protein-altering or splice-affecting, 17 silent, 86 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, 3'UTR 50, Intron 17, Silent 17, 5'UTR 8, 5'Flank 6, Nonsense Mutation 5, 3'Flank 4, Splice Site 1, RNA 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARFGEF1 | c.3238C>G p.L1080V | Missense Mutation (SNP) | VAF 13/328 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV51606894; called by muse, mutect2
- ASTE1 | c.478G>C p.D160H | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53908332; called by muse, mutect2
- DCAF12L1 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV64422169; called by muse, mutect2
- DNAJB4 | c.365C>T p.S122F | Missense Mutation (SNP) | VAF 20/287 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.078); catalogued as rs267598730, COSV100883452; called by muse, mutect2
- DSEL | c.2555C>T p.S852F | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.094); catalogued as COSV100026237; called by muse, mutect2
- FAM160B1 | c.964C>T p.Q322* | Nonsense Mutation (SNP) | VAF 16/78 reads (21%) | catalogued as COSV100985307; called by muse, mutect2, varscan2
- FAM220A | c.681C>G p.F227L | Missense Mutation (SNP) | VAF 90/197 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs559612916, COSV57627608; called by muse, mutect2
- GRID2 | c.2605G>A p.D869N | Missense Mutation (SNP) | VAF 18/274 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV56232405; called by muse, mutect2
- MCTP1 | c.1492C>T p.R498W | Missense Mutation (SNP) | VAF 234/459 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs558503942, COSV56527586; called by muse, mutect2, varscan2
- NPEPL1 | c.89_97del p.H30_H32del | In Frame Del (DEL) | VAF 13/26 reads (50%) | catalogued as rs1276124636; called by mutect2, varscan2
- NUPR2 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1184814651; called by muse, mutect2, varscan2
- PCSK5 | c.4892G>A p.G1631E | Missense Mutation (SNP) | VAF 72/130 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1360127953; called by muse, mutect2, varscan2
- PLSCR5 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 66/154 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.271); catalogued as rs547743521, COSV71649012; called by muse, mutect2, varscan2
- PSMB8 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 77/148 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1411656923; called by muse, mutect2, varscan2
- RPRD2 | c.435G>C p.L145F | Missense Mutation (SNP) | VAF 80/251 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.98); catalogued as rs1553894320; called by muse, mutect2, varscan2
- TFCP2L1 | c.569G>C p.R190P | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99748074; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1019G>C p.R340T | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.092); catalogued as rs777853481; called by muse, mutect2
- VPS39 | c.529A>G p.I177V (on ENST00000348544 / NM_001301138.2; = p.I166V on NM_015289.5) | Missense Mutation (SNP) | VAF 88/176 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.108); catalogued as rs139676322; called by muse, varscan2
- WNT7B | c.781C>G p.Q261E | Missense Mutation (SNP) | VAF 115/124 reads (93%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100255384; called by muse, mutect2, varscan2
- XIRP2 | c.1728G>T p.M576I (on ENST00000628543; = p.M751I on NM_152381.6) | Missense Mutation (SNP) | VAF 38/240 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV54718667; called by muse, mutect2, varscan2
- ZFHX4 | c.9331G>A p.G3111R | Missense Mutation (SNP) | VAF 28/251 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775472372, COSV50502233, COSV50619821, COSV99268389; called by muse, mutect2, varscan2
- ZNF521 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.402); catalogued as rs1485315804, COSV100832097; called by muse, mutect2, varscan2
- ACTR3B | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 88/199 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- ANGPT4 | c.796C>G p.R266G | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP9B | c.1061G>A p.G354E | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AVIL | c.2198C>T p.A733V | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCBE1 | c.446T>A p.I149N | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- CENPF | c.2935C>G p.L979V | Missense Mutation (SNP) | VAF 4/79 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CNTN3 | c.62T>A p.L21H | Missense Mutation (SNP) | VAF 67/141 reads (48%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CUX2 | c.3046G>C p.E1016Q | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- DDX46 | c.2534A>C p.N845T | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- DTX1 | c.118T>C p.Y40H | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EGFLAM | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- EIF3E | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.16); called by muse, mutect2
- EIF4A1 | c.103G>C p.D35H | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.099); called by muse, mutect2
- EXOC3 | c.1651G>C p.E551Q | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.944); called by muse, mutect2
- FBXL14 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HRH1 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.82); PolyPhen benign (0.001); called by muse, mutect2
- INTS6 | c.995C>A p.S332* | Nonsense Mutation (SNP) | VAF 35/111 reads (32%) | called by muse, mutect2, varscan2
- KMT2C | c.4069G>T p.E1357* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2
- MCM4 | c.104A>G p.Q35R | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2
- MCM4 | c.106A>G p.R36G | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.136); called by muse, mutect2
- NEDD4L | c.1208A>G p.Y403C (on ENST00000400345 / NM_001144967.3; = p.Y383C on NM_015277.6) | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NOC2L | c.2023G>A p.E675K | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- NRIP1 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PKIA | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 11/296 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- PLXND1 | c.4966G>C p.D1656H | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- RAB11FIP1 | c.671C>G p.S224* | Nonsense Mutation (SNP) | VAF 13/338 reads (4%) | called by muse, mutect2
- RAD51C | c.1030C>T p.Q344* | Nonsense Mutation (SNP) | VAF 14/295 reads (5%) | called by muse, mutect2
- ROBO2 | c.4135+1G>A p.X1379_splice | Splice Site (SNP) | VAF 66/480 reads (14%) | called by muse, mutect2, varscan2
- RPS19 | c.25_34del p.V9Rfs*17 | Frame Shift Del (DEL) | VAF 28/74 reads (38%) | called by mutect2, pindel, varscan2
- RTTN | c.4750C>T p.H1584Y | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SHANK1 | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC4A3 | c.432G>C p.E144D | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TGFBR1 | c.1339G>C p.E447Q | Missense Mutation (SNP) | VAF 84/199 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- UQCRB | c.185G>C p.R62P | Missense Mutation (SNP) | VAF 66/134 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XKR7 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.138); called by muse, mutect2
- ZSCAN4 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 11/230 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.191); called by muse, mutect2
- BCL2L10 | c.297G>A p.T99= | Silent (SNP) | VAF 43/149 reads (29%) | catalogued as rs1377381261; called by muse, mutect2, varscan2
- CACUL1 | c.486G>A p.Q162= | Silent (SNP) | VAF 65/162 reads (40%) | called by muse, mutect2, varscan2
- CCDC168 | c.1701G>A p.P567= | Silent (SNP) | VAF 49/49 reads (100%) | catalogued as rs748072636; called by muse, mutect2, varscan2
- EPS8L1 | c.1842G>C p.S614= (on ENST00000201647 / NM_133180.3; = p.S487= on NM_017729.3) | Silent (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2, varscan2
- ESPL1 | c.3102G>A p.K1034= | Silent (SNP) | VAF 11/94 reads (12%) | called by muse, mutect2, varscan2
- FREM2 | c.6192C>T p.I2064= | Silent (SNP) | VAF 112/117 reads (96%) | catalogued as rs1171070058; called by muse, mutect2, varscan2
- IFNA2 | c.159G>A p.L53= | Silent (SNP) | VAF 17/164 reads (10%) | called by muse, mutect2, varscan2
- KIDINS220 | c.1842G>A p.L614= | Silent (SNP) | VAF 82/206 reads (40%) | catalogued as rs757803031; called by muse, mutect2, varscan2
- MAP3K14 | c.159A>T p.G53= | Silent (SNP) | VAF 124/269 reads (46%) | catalogued as COSV60923851; called by muse, mutect2, varscan2
- PGLYRP2 | c.1239C>T p.Y413= | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as COSV52997845; called by muse, mutect2, varscan2
- SENP3 | c.1419G>C p.V473= | Silent (SNP) | VAF 27/64 reads (42%) | called by muse, mutect2, varscan2
- SFT2D1 | c.69G>T p.L23= | Silent (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2
- SPAG9 | c.3012C>T p.L1004= (on ENST00000262013 / NM_001130528.3; = p.L990= on NM_003971.6) | Silent (SNP) | VAF 46/88 reads (52%) | catalogued as COSV56242932; called by muse, mutect2, varscan2
- TTN | c.16365A>G p.E5455= (on ENST00000591111; = p.E4528= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 80/168 reads (48%) | called by muse, mutect2, varscan2
- VPS13C | c.7755A>G p.S2585= (on ENST00000644861 / NM_020821.3; = p.S2542= on NM_017684.5) | Silent (SNP) | VAF 5/85 reads (6%) | called by muse, mutect2
- ZFAND5 | c.9G>A p.Q3= | Silent (SNP) | VAF 15/299 reads (5%) | called by muse, mutect2
- ZNF675 | c.78G>T p.R26= | Silent (SNP) | VAF 127/290 reads (44%) | catalogued as COSV63096160; called by muse, mutect2, varscan2
- AC008676.3 | c.*974G>T | 3'UTR (SNP) | VAF 47/107 reads (44%) | called by muse, mutect2, varscan2
- AFG3L2 | c.*59C>T | 3'UTR (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- ALMS1P1 | chr2:73701224 G>A | 3'Flank (SNP) | VAF 62/127 reads (49%) | catalogued as rs759218087; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503995 C>G | 5'Flank (SNP) | VAF 44/153 reads (29%) | catalogued as rs755939890; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498004 C>G | 5'Flank (SNP) | VAF 67/254 reads (26%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499503 T>A | 5'Flank (SNP) | VAF 57/175 reads (33%) | called by muse, mutect2, varscan2
- APBA2 | c.*499C>T | 3'UTR (SNP) | VAF 10/119 reads (8%) | called by muse, mutect2
- BCL7A | chr12:122021349 del CCTACAAC | 5'Flank (DEL) | VAF 20/85 reads (24%) | called by mutect2, pindel, varscan2
- BCL7A | chr12:122021520 A>G | 5'Flank (SNP) | VAF 30/56 reads (54%) | catalogued as COSV55848486; called by muse, mutect2, varscan2
- C1orf158 | c.*10C>A | 3'UTR (SNP) | VAF 31/77 reads (40%) | catalogued as rs1166147207; called by muse, mutect2, varscan2
- C1orf158 | c.*1149A>G | 3'UTR (SNP) | VAF 19/49 reads (39%) | called by muse, varscan2
- C1orf158 | c.*1216A>C | 3'UTR (SNP) | VAF 34/78 reads (44%) | called by muse, varscan2
- CAPN6 | c.*1276C>G | 3'UTR (SNP) | VAF 21/35 reads (60%) | called by muse, mutect2, varscan2
- CCDC170 | c.*2060G>T | 3'UTR (SNP) | VAF 38/44 reads (86%) | called by muse, varscan2
- CCSER2 | c.*413C>T | 3'UTR (SNP) | VAF 217/556 reads (39%) | catalogued as rs946912354; called by muse, mutect2, varscan2
- CDC123 | c.985-110G>C | Intron (SNP) | VAF 33/48 reads (69%) | called by muse, mutect2
- CEP135 | c.699+275G>C | Intron (SNP) | VAF 54/113 reads (48%) | called by muse, mutect2, varscan2
- CMTM3 | c.*56C>G | 3'UTR (SNP) | VAF 29/74 reads (39%) | called by muse, mutect2, varscan2
- CXXC4 | c.*2177dup | 3'UTR (INS) | VAF 16/50 reads (32%) | called by mutect2, pindel, varscan2
- DDX21 | c.*1570G>C | 3'UTR (SNP) | VAF 64/120 reads (53%) | called by muse, varscan2
- DDX21 | c.*1684C>A | 3'UTR (SNP) | VAF 14/32 reads (44%) | called by muse, varscan2
- DPP9 | c.-230+49C>T | Intron (SNP) | VAF 49/96 reads (51%) | called by muse, mutect2, varscan2
- EIF3E | c.1300-150G>C | Intron (SNP) | VAF 17/38 reads (45%) | called by muse, mutect2, varscan2
- EIF3E | c.471+1480G>A | Intron (SNP) | VAF 7/74 reads (9%) | called by muse, mutect2
- ELP4 | chr11:31785613 T>C | 3'Flank (SNP) | VAF 77/81 reads (95%) | called by muse, mutect2, varscan2
- ENO1 | c.-61T>G | 5'UTR (SNP) | VAF 71/130 reads (55%) | catalogued as rs1462855429; called by muse, mutect2, varscan2
- EXOC8 | c.*680C>G | 3'UTR (SNP) | VAF 68/207 reads (33%) | called by muse, mutect2, varscan2
- EXOG | c.*26G>A | 3'UTR (SNP) | VAF 107/241 reads (44%) | catalogued as rs376254637; called by muse, mutect2, varscan2
- FBXL21P | n.975-480C>G | Intron (SNP) | VAF 54/124 reads (44%) | catalogued as rs758731620; called by muse, mutect2, varscan2
- FCGR1B | chr1:121097614 C>T | 3'Flank (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2, varscan2
- FTMT | c.*58C>T | 3'UTR (SNP) | VAF 132/491 reads (27%) | called by muse, mutect2, varscan2
- GCSAML | c.*1071C>T | 3'UTR (SNP) | VAF 85/352 reads (24%) | called by muse, mutect2, varscan2
- GNPTAB | c.*563G>C | 3'UTR (SNP) | VAF 42/86 reads (49%) | called by muse, mutect2, varscan2
- GPHN | c.-430C>G | 5'UTR (SNP) | VAF 125/269 reads (46%) | called by muse, mutect2, varscan2
- GPRC5C | c.*235G>A | 3'UTR (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- HECTD4 | c.8400+386C>G | Intron (SNP) | VAF 37/85 reads (44%) | called by muse, mutect2, varscan2
- HYDIN | c.1044-3401C>G | Intron (SNP) | VAF 89/228 reads (39%) | catalogued as rs1159734065; called by muse, mutect2, varscan2
- IGF2BP3 | c.-349C>T | 5'UTR (SNP) | VAF 40/60 reads (67%) | called by muse, mutect2, varscan2
- IRF4 | c.*956C>G | 3'UTR (SNP) | VAF 10/74 reads (14%) | called by muse, mutect2, varscan2
- ITGB1 | c.*41G>C | 3'UTR (SNP) | VAF 8/227 reads (4%) | called by muse, mutect2
- ITPR1 | c.6784+138G>A | Intron (SNP) | VAF 21/39 reads (54%) | called by muse, varscan2
- JAGN1 | c.*231G>C | 3'UTR (SNP) | VAF 25/61 reads (41%) | called by muse, mutect2, varscan2
- KBTBD11 | c.*415C>A | 3'UTR (SNP) | VAF 34/61 reads (56%) | called by muse, mutect2, varscan2
- LAIR1 | c.35-130T>A | Intron (SNP) | VAF 9/160 reads (6%) | called by muse, mutect2
- LNPEP | c.*746G>C | 3'UTR (SNP) | VAF 7/165 reads (4%) | called by muse, mutect2
- LRAT | c.*2848G>T | 3'UTR (SNP) | VAF 44/108 reads (41%) | called by muse, mutect2, varscan2
- MDGA2 | c.*437A>T | 3'UTR (SNP) | VAF 49/87 reads (56%) | called by muse, mutect2, varscan2
- MED1 | c.*633C>T | 3'UTR (SNP) | VAF 8/141 reads (6%) | catalogued as rs1018205763; called by muse, mutect2
- METTL5 | c.-307C>A | 5'UTR (SNP) | VAF 32/70 reads (46%) | called by muse, mutect2, varscan2
- MKNK1 | c.*972G>A | 3'UTR (SNP) | VAF 46/83 reads (55%) | called by muse, mutect2, varscan2
- MNT | c.-66C>A | 5'UTR (SNP) | VAF 10/20 reads (50%) | called by muse, mutect2, varscan2
- MRPL51 | c.*370G>C | 3'UTR (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2, varscan2
- NKAP | c.468-66C>G | Intron (SNP) | VAF 22/44 reads (50%) | called by muse, mutect2, varscan2
- NSMAF | c.1454-16G>A | Intron (SNP) | VAF 118/234 reads (50%) | catalogued as rs1271922704; called by muse, mutect2, varscan2
- NTRK3 | c.*15168T>A | 3'UTR (SNP) | VAF 27/65 reads (42%) | catalogued as rs925800013; called by muse, mutect2, varscan2
- NUP107 | c.*48A>G | 3'UTR (SNP) | VAF 33/70 reads (47%) | called by muse, mutect2, varscan2
- PAM | c.*390C>G | 3'UTR (SNP) | VAF 39/95 reads (41%) | called by muse, mutect2, varscan2
- PCDH11X | c.*706G>C | 3'UTR (SNP) | VAF 59/348 reads (17%) | called by muse, mutect2, varscan2
- POU2F1 | c.*8161G>T | 3'UTR (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- PTGR1 | chr9:111603692 C>G | 5'Flank (SNP) | VAF 119/280 reads (43%) | called by muse, mutect2, varscan2
- PVR | c.*872G>C | 3'UTR (SNP) | VAF 54/118 reads (46%) | called by muse, mutect2, varscan2
- RAD18 | c.*1956G>C | 3'UTR (SNP) | VAF 31/52 reads (60%) | called by muse, mutect2, varscan2
- RAD9A | c.*75C>G | 3'UTR (SNP) | VAF 26/90 reads (29%) | called by muse, mutect2, varscan2
- REEP3 | c.*2400T>A | 3'UTR (SNP) | VAF 5/63 reads (8%) | called by muse, mutect2
- RPRD2 | c.436+421G>A | Intron (SNP) | VAF 37/124 reads (30%) | called by muse, mutect2, varscan2
- RXFP1 | c.*343G>A | 3'UTR (SNP) | VAF 32/88 reads (36%) | called by muse, mutect2, varscan2
- SAMD14 | c.942+48C>G | Intron (SNP) | VAF 76/162 reads (47%) | called by muse, mutect2, varscan2
- SCAI | c.*676C>G | 3'UTR (SNP) | VAF 40/111 reads (36%) | called by muse, mutect2, varscan2
- SDC4 | c.*1428A>G | 3'UTR (SNP) | VAF 19/46 reads (41%) | called by muse, mutect2, varscan2
- SENP3 | c.1067+54G>A | Intron (SNP) | VAF 17/31 reads (55%) | catalogued as rs903208921; called by muse, mutect2, varscan2
- SLC66A1L | n.372C>G | RNA (SNP) | VAF 35/79 reads (44%) | catalogued as rs751358604, COSV56600299; called by muse, mutect2, varscan2
- SLU7 | c.1287+104T>A | Intron (SNP) | VAF 6/84 reads (7%) | catalogued as rs1377636521; called by muse, mutect2
- SMARCE1 | c.*643C>T | 3'UTR (SNP) | VAF 20/89 reads (22%) | called by muse, mutect2, varscan2
- SOCS1 | c.*171C>T | 3'UTR (SNP) | VAF 16/93 reads (17%) | catalogued as rs981567045; called by muse, mutect2, varscan2
- STPG2 | c.*2772T>C | 3'UTR (SNP) | VAF 64/141 reads (45%) | called by muse, mutect2, varscan2
- STX1A | c.*231G>A | 3'UTR (SNP) | VAF 10/89 reads (11%) | called by mutect2, varscan2
- TBC1D19 | c.-77C>T | 5'UTR (SNP) | VAF 79/164 reads (48%) | called by muse, mutect2, varscan2
- TKFC | chr11:61352950 C>G | 3'Flank (SNP) | VAF 30/868 reads (3%) | called by muse, mutect2
- TSC22D3 | c.*603G>A | 3'UTR (SNP) | VAF 38/83 reads (46%) | called by muse, mutect2, varscan2
- TTC8 | c.*151G>C | 3'UTR (SNP) | VAF 27/62 reads (44%) | called by muse, mutect2, varscan2
- UACA | c.*1167G>C | 3'UTR (SNP) | VAF 7/110 reads (6%) | called by muse, mutect2
- UBE2A | c.*437G>C | 3'UTR (SNP) | VAF 32/76 reads (42%) | called by muse, mutect2, varscan2
- UBE3B | c.631-256_631-255dup | Intron (INS) | VAF 16/32 reads (50%) | called by mutect2, pindel, varscan2
- UCHL5 | c.-166C>G | 5'UTR (SNP) | VAF 106/348 reads (30%) | catalogued as rs977443312; called by muse, mutect2, varscan2
- VPS37B | c.*1750G>A | 3'UTR (SNP) | VAF 14/31 reads (45%) | called by muse, mutect2, varscan2
- ZNF563 | c.-141T>C | 5'UTR (SNP) | VAF 77/140 reads (55%) | called by muse, mutect2, varscan2
